Somatic mutation profile of tumor specimen TCGA-QQ-A8VB-01A (aliquot TCGA-QQ-A8VB-01A-11D-A37C-09) from TCGA case TCGA-QQ-A8VB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 68.2 years (24,916 days).
Specimen TCGA-QQ-A8VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79165a9b-272f-4ceb-9562-5d1de91bfe39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A8VB-10A (Blood Derived Normal), aliquot TCGA-QQ-A8VB-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cbb6393-047b-4c39-b8ba-b2263c396793

The open-access MAF lists 65 somatic variants for this specimen: 54 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 8, Nonsense Mutation 5, 5'UTR 2, Frame Shift Del 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV100441566; called by muse, mutect2, varscan2
- AGBL1 | c.1337G>T p.S446I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV66850597; called by muse, mutect2, varscan2
- AKAP9 | c.11089G>A p.V3697I (on ENST00000359028; = p.V3673I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV100663059; called by muse, mutect2, varscan2
- ANKFN1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100594166; called by muse, mutect2, varscan2
- ATAD2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs367677216; called by muse, mutect2, varscan2
- ATP2A3 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99988762, COSV99989635; called by muse, mutect2, varscan2
- BNIPL | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99639941; called by muse, mutect2, varscan2
- C7 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100496551, COSV57471678, COSV57472471; called by muse, mutect2, varscan2
- CDH18 | c.2368A>T p.T790S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV99938183; called by muse, mutect2, varscan2
- COL1A1 | c.4306C>T p.R1436C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776631611, COSV99868096; called by muse, mutect2, varscan2
- COL6A3 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99801247; called by muse, mutect2, varscan2
- COL6A3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs1395181953, COSV99801249; called by muse, mutect2, varscan2
- CTNNA2 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100559725, COSV100561980; called by muse, mutect2
- FKBP10 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782758369, COSV100388005; called by muse, mutect2
- GPR32 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99567379; called by muse, mutect2, varscan2
- GRM3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200125543, COSV64475667; called by muse, mutect2, varscan2
- GUSB | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100512760; called by muse, mutect2, varscan2
- IARS2 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs141215374, COSV100228603; called by mutect2, varscan2
- IGKV2-24 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | catalogued as rs765936337; called by muse, mutect2, varscan2
- IL1RL1 | c.1017T>G p.F339L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1245428123, COSV99294505; called by muse, mutect2, varscan2
- IRAK4 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101471843; called by muse, mutect2
- ISG20L2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037346466, COSV100494107, COSV57461542; called by muse, mutect2, varscan2
- ITGAX | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs760133637, COSV99192018; called by muse, mutect2, varscan2
- KLHL4 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs865932566, COSV64148686; called by muse, mutect2, varscan2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2, varscan2
- MIPOL1 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1264706775, COSV100539570; called by muse, mutect2
- MYLIP | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100786031; called by muse, mutect2, varscan2
- NDST2 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100014353; called by muse, mutect2
- NDUFB3 | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99428343; called by muse, mutect2
- NR2C2 | c.1490C>G p.A497G (on ENST00000393102; = p.A516G on NM_003298.5) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100038858; called by muse, mutect2, varscan2
- NRP2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477541916, COSV99785610; called by muse, mutect2, varscan2
- OR11G2 | c.255T>A p.C85* | Nonsense Mutation (SNP) | VAF 41/53 reads (77%) | catalogued as rs773370429, COSV100640047; called by muse, mutect2, varscan2
- OR4K1 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53458798, COSV99579362; called by muse, mutect2, varscan2
- POTEA | c.1330C>T p.L444F (on ENST00000519951 / NM_001005365.2; = p.L398F on NM_001002920.1) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs1192779977; called by muse, mutect2, varscan2
- PRB2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs77906063, COSV101231495; called by mutect2, varscan2
- ROBO4 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs775803636, COSV60623135; called by muse, mutect2, varscan2
- SCN10A | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1294999278, COSV71861574; called by muse, mutect2, varscan2
- SCUBE1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 53/57 reads (93%) | catalogued as COSV99298623; called by muse, mutect2, varscan2
- SEL1L | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100378101; called by muse, mutect2, varscan2
- SLC25A28 | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100979640, COSV65125146; called by muse, mutect2, varscan2
- SMO | c.884G>C p.C295S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99977084; called by muse, mutect2
- SOX6 | c.426G>C p.M142I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100323191; called by muse, mutect2
- SUZ12 | c.1438-1G>A p.X480_splice | Splice Site (SNP) | VAF 13/13 reads (100%) | catalogued as COSV100497077; called by muse, mutect2, varscan2
- TMEM43 | c.443-2A>T p.X148_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100044564; called by muse, mutect2, varscan2
- TNRC18 | c.5209G>T p.E1737* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101269878; called by muse, mutect2, varscan2
- UMOD | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as COSV100208673; called by muse, mutect2, varscan2
- VAV1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV100409464; called by muse, mutect2, varscan2
- ZNF599 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201767558; called by mutect2, varscan2
- ZNF85 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100060134; called by muse, mutect2, varscan2
- ZNF91 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV56095258; called by muse, mutect2, varscan2
- ZP4 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV100850775; called by muse, mutect2, varscan2
- LIG3 | c.1473_1488del p.V492Rfs*59 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- SULF2 | c.597C>G p.D199E | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2
- TCEANC2 | c.488del p.C163Sfs*13 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- BEND3 | c.2397C>T p.Y799= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs140272293; called by muse, mutect2, varscan2
- C17orf98 | c.132C>T p.N44= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs373474691; called by muse, mutect2, varscan2
- DGKE | c.828T>A p.V276= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV99401194; called by muse, mutect2, varscan2
- HSD17B1 | c.27C>T p.T9= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as rs139820255; called by muse, mutect2, varscan2
- IGHM | c.891C>T p.S297= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs781861965; called by muse, mutect2, varscan2
- PCDHA4 | c.1974G>A p.A658= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs782214418, COSV100793730; called by muse, mutect2, varscan2
- PCDHB6 | c.594G>A p.P198= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs782776876, COSV99171168; called by muse, mutect2, varscan2
- ZNF365 | c.1122C>T p.C374= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV101237959, COSV101237992, COSV67925145; called by muse, mutect2, varscan2
- ANKRD33 | c.-313G>A | 5'UTR (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100001525; called by muse, mutect2, varscan2
- ELAVL4 | c.-2G>A | 5'UTR (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100836756; called by muse, mutect2
- IGLL3P | n.429G>A | RNA (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
